Gene-level copy-number profile of tumor specimen TCGA-S5-A6DX-01A from TCGA case TCGA-S5-A6DX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 83.8 years (30,594 days).
Specimen TCGA-S5-A6DX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.1f1d50db-48eb-474c-a49b-c5e348d65fae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S5-A6DX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d84e985-9867-4e52-a8de-3aabeec82a45

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 1,309; copy number 2: 9,789; copy number 3: 18,898; copy number 4: 28,783; copy number 5: 773; copy number 6: 15; copy number 7: 40; copy number 10: 6; copy number 11: 25; copy number 13: 47; copy number 14: 3; copy number 15: 43; copy number 16: 2; copy number 17: 4; copy number 18: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S5-A6DX-01A-11D-A31K-01): tumor purity 0.39, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:136,822,564–138,107,419, 25 genes: PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP.
- chr6:150,827,663–150,828,384, 1 gene: PDCL3P5.
- chr6:150,934,968–150,935,566, 1 gene: ARL4AP5.
- chr8:16,598,758–17,002,345, 4 genes: AC011586.2, AC011586.1, RN7SL474P, FGF20.
- chr9:13,274,510–13,323,450, 2 genes: AL162386.2, AL162386.1.
- chr9:21,695,176–22,214,672, 17 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr14:82,429,872–82,430,156, 1 gene: Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 128 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:64,883,394–67,590,771, 51 genes, copy number 13–17 (within-gene range 6–17): LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442.
- chr12:67,929,235–71,118,247, 74 genes, copy number 10–15 (within-gene range 7–15) (broad region; genes not listed).
- chr12:74,656,561–74,728,851, 3 genes, copy number 14: AC123904.2, AC123904.1, AC123904.3.

Autosomal genes at a single copy (total copy number 1): 171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
